Somatic mutation profile of tumor specimen MMRF_2024_1_BM_CD138pos (aliquot MMRF_2024_1_BM_CD138pos_T1_KHS5U_L12870) from MMRF case MMRF_2024, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: female; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 58.7 years (21,435 days).
Specimen MMRF_2024_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a8b69444-76f3-4947-b461-27fa3ea0c95e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_2024_1_PB_CD3pos (Blood Derived Normal), aliquot MMRF_2024_1_PB_CD3pos_C2_KHS5U_L12869; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/dca77401-0aa4-46ec-95ca-ce0e63f21632

The open-access MAF lists 85 somatic variants for this specimen: 37 protein-altering or splice-affecting, 11 silent, 37 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 32, 3'UTR 22, Silent 11, Intron 6, 5'UTR 4, 3'Flank 3, RNA 1, Nonsense Mutation 1, In Frame Del 1, Splice Site 1, Splice Region 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NRAS | c.182A>G p.Q61R | Missense Mutation (SNP) | VAF 66/143 reads (46%) | hotspot (GDC flag); SIFT tolerated (0.06); PolyPhen benign (0.251); catalogued as rs11554290, COSV54736340, COSV54736624, COSV54738969, COSV54747786; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- DGCR8 | c.2165C>T p.A722V | Missense Mutation (SNP) | VAF 8/194 reads (4%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.823); catalogued as rs866996255; called by muse, mutect2
- DGKG | c.1457G>A p.R486H | Missense Mutation (SNP) | VAF 84/200 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs983790707, COSV99404399; called by muse, mutect2, varscan2
- FAT3 | c.2585C>T p.S862F | Missense Mutation (SNP) | VAF 129/308 reads (42%) | SIFT tolerated (0.37); PolyPhen benign (0.286); catalogued as COSV53115782; called by muse, varscan2
- H2BC3 | c.111C>G p.S37R | Missense Mutation (SNP) | VAF 80/178 reads (45%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.664); catalogued as rs1056448275; called by muse, mutect2, varscan2
- HAO1 | c.356C>T p.A119V | Missense Mutation (SNP) | VAF 50/85 reads (59%) | SIFT tolerated (0.23); PolyPhen benign (0.201); catalogued as rs200686504, COSV66493396; called by muse, mutect2, varscan2
- HCN4 | c.944G>A p.R315H | Missense Mutation (SNP) | VAF 46/111 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs759685985, COSV56086261; called by muse, mutect2, varscan2
- IGHV2-70 | c.151A>T p.S51C | Missense Mutation (SNP) | VAF 59/160 reads (37%) | SIFT deleterious (0.03); PolyPhen benign (0.368); catalogued as rs376400758; called by muse, varscan2
- MMP28 | c.657C>A p.D219E | Missense Mutation (SNP) | VAF 24/47 reads (51%) | SIFT deleterious (0.02); PolyPhen benign (0.089); catalogued as rs1555605066; called by muse, mutect2, varscan2
- RABL3 | c.286G>A p.D96N | Missense Mutation (SNP) | VAF 88/193 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs564912172; called by muse, mutect2, varscan2
- ROS1 | c.4140C>T p.L1380= | Splice Region (SNP) | VAF 55/139 reads (40%) | catalogued as rs745716185; called by muse, mutect2, varscan2
- RYR3 | c.8939C>G p.T2980R (on ENST00000389232; = p.T2981R on NM_001036.6) | Missense Mutation (SNP) | VAF 63/197 reads (32%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.755); catalogued as COSV66805061; called by muse, mutect2, varscan2
- SDK1 | c.1346G>A p.R449H | Missense Mutation (SNP) | VAF 98/175 reads (56%) | SIFT tolerated (0.22); PolyPhen benign (0.001); catalogued as rs148101694; called by muse, mutect2, varscan2
- SLC9A9 | c.1541A>G p.D514G | Missense Mutation (SNP) | VAF 50/148 reads (34%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as rs994370251; called by muse, mutect2, varscan2
- THBD | c.271C>A p.Q91K | Missense Mutation (SNP) | VAF 40/97 reads (41%) | SIFT tolerated (0.25); PolyPhen benign (0.001); catalogued as rs1453264247; called by muse, varscan2
- ABCC9 | c.1406T>C p.I469T | Missense Mutation (SNP) | VAF 16/273 reads (6%) | SIFT deleterious (0); PolyPhen benign (0.158); called by muse, mutect2
- APBA2 | c.2228A>T p.Q743L | Missense Mutation (SNP) | VAF 22/219 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.177); called by muse, mutect2
- ASCC3 | c.6075+2T>C p.X2025_splice | Splice Site (SNP) | VAF 36/79 reads (46%) | called by muse, mutect2, varscan2
- CDH10 | c.1081T>A p.Y361N | Missense Mutation (SNP) | VAF 43/105 reads (41%) | SIFT tolerated (0.55); PolyPhen benign (0.041); called by muse, mutect2, varscan2
- CYP4B1 | c.910G>C p.D304H | Missense Mutation (SNP) | VAF 48/100 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- DNAH10 | c.1675del p.D559Tfs*15 (on ENST00000409039; = p.D498Tfs*15 on NM_207437.3) | Frame Shift Del (DEL) | VAF 62/164 reads (38%) | called by mutect2, varscan2
- DNAJC10 | c.144T>G p.S48R | Missense Mutation (SNP) | VAF 30/59 reads (51%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.824); called by muse, mutect2, varscan2
- FLRT3 | c.1311A>T p.R437S | Missense Mutation (SNP) | VAF 11/256 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.776); called by muse, mutect2
- IGHV3-33 | c.17G>C p.S6T | Missense Mutation (SNP) | VAF 22/128 reads (17%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.02); called by muse, varscan2
- IGSF10 | c.4522T>A p.S1508T | Missense Mutation (SNP) | VAF 106/234 reads (45%) | SIFT tolerated (0.49); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- IK | c.826_830delinsCA p.D276_I277delinsH | In Frame Del (DEL) | VAF 20/67 reads (30%) | called by pindel, varscan2*
- KDM3B | c.822G>T p.K274N | Missense Mutation (SNP) | VAF 92/185 reads (50%) | SIFT deleterious (0.02); PolyPhen benign (0.159); called by muse, mutect2, varscan2
- MIA3 | c.165T>G p.D55E | Missense Mutation (SNP) | VAF 85/195 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- MYLK | c.5407G>T p.E1803* | Nonsense Mutation (SNP) | VAF 71/173 reads (41%) | called by muse, varscan2
- MYO10 | c.3214A>G p.T1072A | Missense Mutation (SNP) | VAF 101/243 reads (42%) | SIFT tolerated, low confidence (0.6); PolyPhen benign (0); called by muse, mutect2, varscan2
- NHSL2 | c.860C>T p.S287F (on ENST00000510661; = p.S653F on NM_001013627.2) | Missense Mutation (SNP) | VAF 18/200 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- NRXN1 | c.4072T>A p.C1358S | Missense Mutation (SNP) | VAF 47/92 reads (51%) | SIFT tolerated (0.08); PolyPhen benign (0); called by muse, mutect2, varscan2
- PTPRD | c.2927A>T p.D976V | Missense Mutation (SNP) | VAF 36/97 reads (37%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.565); called by muse, mutect2, varscan2
- RELB | c.684G>C p.Q228H | Missense Mutation (SNP) | VAF 115/255 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); called by muse, mutect2, varscan2
- SPRY4 | c.715G>T p.G239C (on ENST00000434127 / NM_001127496.3; = p.G262C on NM_030964.4) | Missense Mutation (SNP) | VAF 40/88 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.905); called by muse, mutect2, varscan2
- TTYH1 | c.236G>T p.G79V | Missense Mutation (SNP) | VAF 73/210 reads (35%) | SIFT tolerated (0.13); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ZNF852 | c.266A>T p.D89V | Missense Mutation (SNP) | VAF 8/154 reads (5%) | SIFT deleterious (0.04); PolyPhen benign (0.211); called by muse, mutect2
- ADAMTS5 | c.129C>A p.P43= | Silent (SNP) | VAF 17/39 reads (44%) | called by muse, mutect2, varscan2
- ADGB | c.2409G>C p.V803= | Silent (SNP) | VAF 4/72 reads (6%) | called by muse, mutect2
- APOB | c.8694G>C p.L2898= | Silent (SNP) | VAF 96/234 reads (41%) | called by muse, mutect2, varscan2
- C20orf194 | c.2265C>T p.L755= | Silent (SNP) | VAF 48/103 reads (47%) | called by muse, mutect2, varscan2
- CSMD1 | c.9156C>A p.T3052= (on ENST00000520002; = p.T3051= on NM_033225.6) | Silent (SNP) | VAF 25/98 reads (26%) | called by muse, mutect2, varscan2
- GLI2 | c.798C>T p.S266= | Silent (SNP) | VAF 134/304 reads (44%) | catalogued as rs1221628407; called by muse, mutect2, varscan2
- MYOM2 | c.1410G>A p.R470= | Silent (SNP) | VAF 36/69 reads (52%) | called by muse, mutect2, varscan2
- TAF7 | c.273C>T p.I91= | Silent (SNP) | VAF 81/210 reads (39%) | catalogued as rs1366087509; called by muse, mutect2, varscan2
- THBD | c.270G>A p.L90= | Silent (SNP) | VAF 39/97 reads (40%) | called by muse, varscan2
- TRARG1 | c.60C>T p.F20= | Silent (SNP) | VAF 12/212 reads (6%) | catalogued as rs1246149698; called by muse, mutect2
- ZCCHC18 | c.1089C>T p.D363= | Silent (SNP) | VAF 48/54 reads (89%) | called by muse, mutect2, varscan2
- ACSS3 | c.*303T>A | 3'UTR (SNP) | VAF 36/83 reads (43%) | called by muse, mutect2, varscan2
- ALDH3B2 | c.*610C>T | 3'UTR (SNP) | VAF 68/152 reads (45%) | called by muse, mutect2, varscan2
- ARFGEF3 | c.*6542T>C | 3'UTR (SNP) | VAF 33/43 reads (77%) | called by muse, mutect2, varscan2
- BCL11B | c.-100_-99insAGCGGC | 5'UTR (INS) | VAF 4/43 reads (9%) | catalogued as rs1195993811; called by mutect2, pindel
- CADM2 | chr3:86068576 C>G | 3'Flank (SNP) | VAF 41/110 reads (37%) | called by muse, mutect2, varscan2
- CALCRL | c.*1000A>G | 3'UTR (SNP) | VAF 30/67 reads (45%) | called by muse, mutect2, varscan2
- CBL | c.*4778T>C | 3'UTR (SNP) | VAF 51/120 reads (43%) | called by muse, mutect2, varscan2
- CLASP2 | c.-53C>G | 5'UTR (SNP) | VAF 4/16 reads (25%) | called by mutect2, varscan2
- DARS1 | c.217+62A>T | Intron (SNP) | VAF 66/154 reads (43%) | called by mutect2, varscan2
- ELF5 | c.*161G>T | 3'UTR (SNP) | VAF 9/58 reads (16%) | called by muse, mutect2, varscan2
- ELOVL4 | c.*56A>G | 3'UTR (SNP) | VAF 32/71 reads (45%) | catalogued as COSV100876411; called by muse, mutect2, varscan2
- ETS2 | c.-501G>T | 5'UTR (SNP) | VAF 13/29 reads (45%) | called by muse, mutect2, varscan2
- GCNT3 | c.*266G>C | 3'UTR (SNP) | VAF 30/101 reads (30%) | called by muse, mutect2, varscan2
- GMPR2 | c.857+70G>A | Intron (SNP) | VAF 40/82 reads (49%) | catalogued as rs749255727; called by muse, mutect2, varscan2
- HTR3A | c.-84A>G | 5'UTR (SNP) | VAF 33/65 reads (51%) | called by muse, mutect2, varscan2
- IL4R | c.70+868G>A | Intron (SNP) | VAF 58/124 reads (47%) | called by muse, mutect2, varscan2
- KCNJ5 | chr11:128920325 C>T | 3'Flank (SNP) | VAF 84/182 reads (46%) | called by muse, mutect2, varscan2
- KLRK1 | c.-65-52C>G | Intron (SNP) | VAF 99/253 reads (39%) | called by muse, mutect2, varscan2
- MYRFL | c.*194A>T | 3'UTR (SNP) | VAF 35/79 reads (44%) | called by muse, mutect2, varscan2
- NFKBIZ | c.*462G>A | 3'UTR (SNP) | VAF 29/74 reads (39%) | called by muse, varscan2
- NKAIN2 | c.474+245A>C | Intron (SNP) | VAF 67/75 reads (89%) | called by muse, mutect2, varscan2
- NOC2LP2 | n.587T>C | RNA (SNP) | VAF 71/160 reads (44%) | called by muse, mutect2, varscan2
- OSGIN2 | c.*1116A>G | 3'UTR (SNP) | VAF 4/85 reads (5%) | called by muse, mutect2
- OTUB2 | c.*1576A>C | 3'UTR (SNP) | VAF 4/74 reads (5%) | catalogued as rs776747816; called by muse, mutect2
- PTK2 | c.*870T>G | 3'UTR (SNP) | VAF 27/71 reads (38%) | called by muse, mutect2, varscan2
- PTPRK | chr6:127969405 A>C | 3'Flank (SNP) | VAF 72/90 reads (80%) | called by muse, varscan2
- RNF135 | chr17:30971026 A>G | 5'Flank (SNP) | VAF 25/79 reads (32%) | catalogued as rs1477163768; called by muse, mutect2, varscan2
- SLC25A22 | c.203-47A>T | Intron (SNP) | VAF 15/43 reads (35%) | called by muse, mutect2, varscan2
- STX16 | c.*1465C>T | 3'UTR (SNP) | VAF 7/125 reads (6%) | called by muse, mutect2
- TGFBR2 | c.*1533G>A | 3'UTR (SNP) | VAF 25/75 reads (33%) | catalogued as rs952747946; called by muse, mutect2, varscan2
- TKTL1 | c.*408T>A | 3'UTR (SNP) | VAF 110/116 reads (95%) | called by muse, mutect2, varscan2
- TMTC1 | c.*4872T>A | 3'UTR (SNP) | VAF 13/49 reads (27%) | called by muse, mutect2, varscan2
- TMTC1 | c.*4871C>T | 3'UTR (SNP) | VAF 13/49 reads (27%) | catalogued as rs151332410; called by muse, mutect2, varscan2
- TMTC3 | c.*1230A>C | 3'UTR (SNP) | VAF 32/84 reads (38%) | catalogued as rs1264359336; called by muse, mutect2, varscan2
- TNRC6B | c.*12507T>G | 3'UTR (SNP) | VAF 19/45 reads (42%) | called by muse, mutect2, varscan2
- VGLL3 | c.*8715A>T | 3'UTR (SNP) | VAF 48/117 reads (41%) | catalogued as rs1014640625; called by muse, mutect2, varscan2
- ZNF587 | c.*622T>C | 3'UTR (SNP) | VAF 22/56 reads (39%) | called by muse, mutect2, varscan2
